Surgical pathology report (de-identified scan), TCGA case TCGA-CX-7082, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site Medical College of Georgia, specimen TCGA-CX-7082-01A (Primary Tumor).

[page 1 of 7]
TCGA Cx-7988

F i n a l P a t h o l o g y D i a g n o s i s R e p o r t

Accession Number:

Senior Pathologist:

Collected Date/Time:

Received Date/Time:

Verified Date/Time:

Final Pathologic Diagnosis

A) PALATE AND RETROMOLAR TRIGONE (RADICAL TONSILLECTOMY, PARTIAL PALATECTOMY AND RETROMOLAR TRIGONE EXCISION):

- Invasive keratinizing squamous cell carcinoma, moderately differentiated. (See synoptic report)
- Unremarkable tonsillar tissue, negative for malignancy.

B) LATERAL BUCCAL MARGIN (BIOPSY):

- Fibroadipose tissue with smooth muscle, negative for malignancy.

C) DEEP PTERYGOID MARGIN (BIOPSY):

- Fibroadipose tissue with smooth muscle, negative for malignancy.

D) DEEP RETROMOLAR TRIGONE MARGIN (BIOPSY):

- Fibroadipose tissue with submucosal glands, negative for malignancy.

E) INFERIOR BUCCAL MARGIN (BIOPSY):

- Squamous mucosa with cautery artifact, negative for malignancy.

F) PALATE MARGIN (BIOPSY):

- Fibroadipose tissue, negative for malignancy.

G) MEDIAL PHARYNGEAL MARGIN (BIOPSY):

- Squamous mucosa and underlying submucosal glands and smooth muscle with mild chronic inflammation, negative for malignancy.

H) PHARYNGEAL FAT MARGIN (BIOPSY):

- Salivary gland tissue, negative for malignancy.

I) LEVEL 2 (LYMPH NODE DISSECTION):

Printed

[page 2 of 7]
Final Pathology Diagnosis Report

Accession Number:

Senior Pathologist:

Collected Date/Time:

Received Date/Time:

Verified Date/Time:

- Two benign lymph nodes, negative for malignancy (0/2).

J) LEVEL 3 (LYMPH NODE DISSECTION):

- One benign lymph node, negative for malignancy (0/1).

K) MEDIAL LEVEL 5 (LYMPH NODE DISSECTION):

- Nine benign lymph nodes, negative for malignancy (0/9).

L) LEVEL 5 (LYMPH NODE DISSECTION):

- Two of two lymph nodes positive for metastatic squamous cell carcinoma (2/2) with extracapsular extension.

I attest I have personally reviewed the specimen/slides and agree with the above findings.

Resident:

Synoptic Report

A: Lip and Oral Cavity

SPECIMEN (Select all that apply):

Other (specify): Tonsil, palate, retromolar trigone

RECEIVED:

Fresh

PROCEDURE (Select all that apply):

Resection

Palatectomy

SPECIMEN INTEGRITY:

Intact

SPECIMEN SIZE:

Greatest dimensions: 4.8 cm

Printed:

[page 3 of 7]
F i n a l P a t h o l o g y D i a g n o s i s R e p o r t

Accession Number:

Senior Pathologist:

Collected Date/Time:

Received Date/Time:

Verified Date/Time:

SPECIMEN LATERALITY:

Right

TUMOR SITE (Select all that apply):

Other (specify): right retromolar trigone

TUMOR FOCALITY:

Single focus

TUMOR SIZE:

Greatest dimensions: 3.5 cm

Additional dimensions: 1 x 0.3 cm

TUMOR THICKNESS (pT1 AND pT2 Tumors):

Tumor thickness: 4 mm

TUMOR DESCRIPTION (Select all that apply):

Gross subtype

Ulcerated

HISTOLOGIC TYPE (Select all that apply):

Squamous cell carcinoma, conventional

HISTOLOGIC GRADE:

G2: Moderately differentiated

MARGINS (Select all that apply):

Margins uninvolved by invasive carcinoma

Distance from closest margin: 0.2cm. This measurement takes into account the additional margins (Specimen B and Specimen C). While some of the margins on Specimen A appear positive, additional margins were taken in Specimen B through Specimen H.

Specify margin(s), per orientation, if possible: Lateral and deep

LYMPH-VASCULAR INVASION:

Not identified

PERINEURAL INVASION:

Not identified

LYMPH NODES, EXTRANODAL EXTENSION:

Present

PATHOLOGIC STAGING (pTNM):

PRIMARY TUMOR (pT)

pT2: Tumor more than 2 cm but not more than 4 cm in greatest dimension

REGIONAL LYMPH NODES (pN)

pN2b: Metastasis in multiple ipsilateral lymph nodes, none more than 6 cm in greatest dimension

Specify: Number examined: 15

Number involved: 2

DISTANT METASTASIS

Not Applicable

Printed:

[page 4 of 7]
F i n a l P a t h o l o g y D i a g n o s i s R e p o r t

Accession Number:

Senior Pathologist:

Collected Date/Time:

Received Date/Time:

Verified Date/Time:

ADDITIONAL PATHOLOGIC FINDINGS (Select all that apply):

Keratinizing dysplasia

Moderate

Intraoperative Diagnosis

FS B1: Margin negative for tumor.

FS C1: Margin negative for tumor.

FS D1: Margin negative for tumor.

FS E1: Margin negative for tumor.

FS F1: Margin negative for tumor.

FS G1: Margin negative for tumor.

FS H1: Margin negative for tumor.

Clinical History

male.

Pre/Post-operative Diagnosis

SCCA right retromolar trigone mass.

Gross Anatomic Description

Specimens received in twelve containers.

Specimen A: Designated "radical tonsillectomy, partial palatectomy, retromolar trigone excision" is received in formalin labeled with the patient's name, MRN and "radical tonsillectomy, partial palatectomy, retromolar trigone excision". Specimen consists of a single irregular portion of soft tissue with a mucosal surface which measures 4.8 x 2.9 x 0.6 cm in aggregate. The specimen is oriented. The mucosal surface is tan/ pink with a roughly central portion of ulceration measuring 3.5 x 1 x 0.3 cm. The specimen came with the deep margin previously inked blue. Cut surface reveals firm and somewhat fibrotic area underlying the ulceration which grossly abuts the deep inked margins.

Inking code: Black – lateral; green –medial; Red – superior; Orange – inferior; blue – deep.

Section code: A1 – medial margin, perpendicularly sectioned; A2 – lateral margin perpendicular sections; A3-A8 – sections of specimen submitted from medial to lateral, entire specimen.

Printed:

[page 5 of 7]
F i n a l P a t h o l o g y D i a g n o s i s R e p o r t

Accession Number:

Senior Pathologist:

Collected Date/Time:

Received Date/Time:

Verified Date/Time:

Specimen B: Designated "lateral buccal margin" is received fresh for intraoperative consultation and frozen section diagnosis on [REDACTED] labeled with the patient's name and "lateral buccal margin". Specimen consists of one piece of tan tissue measuring 0.2 x 0.5 x 0.3 cm, entirely frozen.

Section code: B1 – frozen section control, entire specimen.

Specimen C: Designated "deep pterygoid margin" is received fresh for intraoperative consultation and frozen section diagnosis on [REDACTED] labeled with the patient's name and "deep pterygoid margin". Specimen consists of one piece of red tissue measuring 0.7 x 0.5 x 0.2 cm, entirely frozen.

Section code: B1 – frozen section control, entire specimen.

Specimen D: Designated "deep retromolar trigone margin" is received fresh for intraoperative consultation and frozen section diagnosis on [REDACTED] labeled with the patient's name and "deep retromolar trigone margin". Specimen consists of one piece of tan tissue measuring 0.6 x 0.4 x 0.2 cm, entirely frozen.

Section code: D1 – frozen section control, entire specimen.

Specimen E: Designated "inferior buccal margin" is received fresh for intraoperative consultation and frozen section diagnosis on [REDACTED] labeled with the patient's name and "inferior buccal margin". Specimen consists of one piece of tan tissue measuring 0.4 x 0.2 x 0.1 cm, entirely frozen.

Section code: E1 – frozen section control, entire specimen.

Specimen F: Designated "palate margin" is received fresh for intraoperative consultation and frozen section diagnosis on [REDACTED] labeled with the patient's name and "palate margin". Specimen consists of one piece of tan tissue measuring 1.3 x 0.4 x 0.3 cm, entirely frozen.

Section code: F1 – frozen section control, entire specimen.

Specimen G: Designated "medial pharyngeal margin" is received fresh for intraoperative consultation and frozen section diagnosis on [REDACTED] labeled with the patient's name and "medial pharyngeal margin". Specimen consists of one piece of tan tissue measuring 0.7 x 0.5 x 0.3 cm, entirely frozen.

Section code: G1 – frozen section control, entire specimen.

Specimen H: Designated "pharyngeal fat margin" is received fresh for intraoperative consultation and frozen section diagnosis on [REDACTED] labeled with the patient's name and "pharyngeal fat margin". Specimen consists of one piece of pink/tan tissue measuring 1.3 x 0.7 x 0.4 cm, trisected and entirely frozen.

Section code: H1 – frozen section control, entire specimen.

Specimen I: Designated "level 2" is received in formalin labeled with the patient's name and "level 2". Specimen consists of a single portion of soft tan/ yellow bosselated fibroadipose tissue measuring 3.8 x 2.9 x 0.6 cm. Two lymph nodes are grossly appreciated ranging from 0.4 cm to 1.0 cm in diameter.

Section code: I1 – I2 – one lymph node each bisected.

Printed [REDACTED]

[page 6 of 7]
F i n a l P a t h o l o g y D i a g n o s i s R e p o r t

Accession Number:

Senior Pathologist:

Collected Date/Time:

Received Date/Time:

Verified Date/Time:

Specimen J: Designated "level 3" is received in formalin labeled with the patient's name and "level 3". Specimen consists of a single portion of soft tan/ yellow bosselated fibroadipose tissue measuring 3.1 x 2.1 x 0.7 cm. One lymph node is identified measuring 0.8 cm in diameter.

Section code: J1 – one lymph node each bisected.

Specimen K: Designated "medial level 5" is received in formalin labeled with the patient's name and "medial level 5".

Specimen consists of a single portion of soft tan/ yellow bosselated fibroadipose tissue measuring 2.5 x 1.8 x 0.3 cm. No lymph nodes are grossly appreciated.

Section code: K1–K2 – entire specimen.

Specimen L: Designated "level 5" is received fresh for Tumor Bank labeled with the patient's name and "level 5". Specimen consists of a single portion of soft tan/ yellow bosselated fibroadipose tissue measuring 4.5 x 2.5 x 0.6 cm. A portion of one lymph node is given for Tumor Bank. Two lymph nodes are grossly identified ranging from 0.6 cm to 0.8 cm.

Section code: L1–one lymph node bisected minus portion given to Tumor Bank; L2 – one lymph node bisected.

Printed:

[page 7 of 7]
I n t r a o p e r a t i v e D i a g n o s i s R e p o r t

Accession Number:

Senior Pathologist:

Collected Date/Time:

Received Date/Time:

Verified Date/Time:

Intraoperative Diagnosis

FS B1: Margin negative for tumor.
FS C1: Margin negative for tumor.
FS D1: Margin negative for tumor.
FS E1: Margin negative for tumor.
FS F1: Margin negative for tumor.
FS G1: Margin negative for tumor.
FS H1: Margin negative for tumor.

Printed:

Source: NCI Genomic Data Commons file 3f2ead8a-2220-468c-ac62-904118021e09 (TCGA-CX-7082.872BE720-140A-4152-84CE-184D1A2CDFE7.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).